Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BQ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BQ-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with left thigh sarcoma, status post excisional biopsy here for re-excision.

Specimens Submitted:

- 1: SP: Posterior left thigh sarcoma
- 2: SP: Posterior and lateral nodule left thigh

DIAGNOSIS:

- 1. SOFT TISSUE, LEFT POSTERIOR THIGH; RESECTION:
- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA, STORIFORM AND PLEOMORPHIC TYPE, INVOLVING SUBCUTANEOUS FIBROADIPOSE TISSUE AND EXTENDING TO DERMIS.
- TUMOR DIMENSIONS: 6 X 4.5 X 3 CM.
- GROSSLY THE TUMOR APPEARS TO HAVE \R\ 30% NECROSIS.
- PREVIOUS PROCEDURE RELATED CHANGES.
- SURGICAL MARGINS ARE NEGATIVE.
- 2. SOFT TISSUE, LEFT POSTERIOR AND LATERAL THIGH; EXCISION:
- LOBULATED ADIPOSE TISSUE CONSISTENT WITH LIPOMA.
- TUMOR DIMENSIONS: 6 X 4 X 2 CM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh, labeled "posterior left thigh sarcoma, 1 stitch proximal/lateral, 2 stitches distal/medial" and consists of an oriented piece of skin and soft tissue measuring 15.6 x 10 x 4 cm in overall dimensions. There is an overlying tan-beige skin ellipse measuring 15.3 x 2.9 cm with a centrally located sutured scar area measuring 4.5 cm. The specimen is inked as follows: Proximal yellow, distal blue, lateral orange, medial

** Continued on next page **

ICD O-3
Fibrosarcoma, fibrous, malignant
pleomorphic 8830/3
Site ④ thigh NOS C49.2
JN 11/22/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3
red, anterior green and deep black. The specimen is bisected along its longitudinal axis to reveal a well circumscribed, unencapsulated tan-grey hemorrhagic mass measuring 6 x 4.5 x 3 cm. Grossly the tumor appears \R\ 30% necrotic. The mass is located the following distances from the respective margins: 0.3 cm from anterior/skin, 0.5 cm from deep, 6 cm from proximal, 7 cm from distal, 1.5 cm from medial and 3 cm from lateral. Photographs are taken and a portion of the tumor is submitted for TPS. Representative sections are submitted.

Summary of sections:

PM proximal margin
DM distal margin
LM lateral margin
MMT medial margin with tumor
DMT deep margin with tumor
SKT skin with tumor
T tumor

2.) The specimen is in formalin, labeled "posterior and lateral nodule left thigh" and consists of an unoriented piece of fatty tissue measuring 6 x 4 x 2 cm. The specimen is entirely inked black and serially sectioned to reveal a homogenous yellow fatty cut surface with no gross lesions identified. Representative sections are submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Posterior left thigh sarcoma

Block	Sect.	Site	PCs
1		AMT	1
1		DM	1
1		DMT	1
1		LM	1
1		PM	1
1		SKT	1
4		T	4

Part 2: SP: Posterior and lateral nodule left thigh

Block	Sect.	Site	PCs
4		U	4

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 74fecc5d-aa5d-409e-a533-3539f1b2e9ca (TCGA-DX-A8BQ.43D9170A-5213-4ED3-BA97-CA26FCD96A09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).